Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A55W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A55W-01A (Primary Tumor).

[page 1 of 3]
Collection Date

Collection Time

Resulting Agency

SURGICAL PATHOLOGY

PATHOLOGIC DIAGNOSIS

A. KIDNEY, RIGHT, TUMOR BASE RESECTION:

- NO MALIGNANCY IDENTIFIED

B. KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA
- NO SARCOMATOID FEATURES IDENTIFIED
- FUHRMAN NUCLEAR GRADE 3
- TUMOR FOCALITY: UNIFOCA
- GREATEST DIMENSION: AT LEAST 4.5 CM
- PLEASE SEE COMMENT
- NO TUMOR NECROSIS IDENTIFIED
- TUMOR LIMITED TO THE KIDNEY
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- MARGINS OF RESECTION FREE OF TUMOR

TUMOR STAGING (PATHOLOGY)

Anatomic site of cancer: Right kidney

Histologic type: Papillary renal cell carcinoma

Histologic grade: Fuhrman nuclear grade 3

Tumor size: At least 4.5 cm (Please see comment)

Primary Tumor (T): T1b

Lymph node (N): NX

Distant Metastases (M): MX

Stage Grouping: I

Margins: Negative

ICD-0-3

carcinoma, papillary renal cell
8260/3

Site: Kidney, NOS C64.9

in
11/25/12

Staff Pathologist

[page 2 of 3]
Comment

The resection specimen was received in two pieces. The main piece, the portion of kidney and tumor, showed the tumor to be 4 cm in greatest dimension and the separate piece that was friable tumor measured 4.5 cm in greatest dimension. Clinical evaluation for tumor size may be more accurate.

Intraoperative Consultation

Intraoperative Frozen Section Diagnosis

FSA: Kidney, right base resection biopsy:

- No malignancy identified

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

year-old Black male with right renal mass.

Gross Description

Specimen Material: A- Tumor base resection (right kidney), B- Right kidney tumor.

The case is received in two parts each labeled with the patient's name, medical record number and given accession number , and it is accompanied by a requisition form labeled with the same name and same accession number.

Part A: Received fresh labeled "TUMOR BASE RESECTION (RIGHT KIDNEY)" is a 0.8 x 0.3 x 0.3 cm tan-pink irregular portion of tissue. No masses or lesions are identified. A frozen section is performed and the specimen is submitted in its entirety into one cassette labeled FSA1.

Part B: Received in formalin labeled "RIGHT KIDNEY TUMOR" is a 51 gram, 4 x 3.5 x 2.5 cm red-brown, ovoid portion of kidney with abundant attached fat and Gerota's fascia. Also received in the container is a 14 gram tan portion of friable tissue that measures 4.5 x 3 x 3 cm that entirely represents tumor. The Gerota's fascia above the attached fat is inked blue and the kidney resection margin is inked black. The specimen is serially sectioned to reveal a well-circumscribed tan to tan-pink and variegated, friable mass that is located 0.1 cm from the nearest renal resection margin and abuts the soft tissue margin. The attached fat is sectioned and lymph node search is performed and reveals no grossly identifiable lymph nodes. Gross pictures are taken.

Representative sections are submitted as follows:

B1: tumor to nearest kidney resection margin

[page 3 of 3]
B2: representative sections of tumor and nearest soft tissue margin
B3: other half of tumor to nearest soft tissue margin
B4-B7: representative sections of tumor to kidney resection margin
B8: representative sections of tumor capsule to soft tissue margin
B9-B10: representative section of tumor to kidney resection margin
B11: representative section of soft tissue margin and opposite end of
farthest extent of uninvolved kidney

Pathology Resident

Pathology Resident
Microscopic Description
Performed.

The staff pathologist listed below has reviewed this case.

****Electronically Signed Out****

Staff Pathologist

1st St. Discrepancy		☒

Source: NCI Genomic Data Commons file 0f8bb124-9150-4707-aa20-20ce3be56ec7 (TCGA-MH-A55W.46238E10-14E8-43E2-BC3C-BE71BBDD936D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).